CGCI case BLGSP-71-06-00164 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7e0e68c6-4055-485c-8d34-651e803af78c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 7 years; Vital status: Dead; Days to death: 8 days.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Liver; Classification of tumor: primary; Year of diagnosis: 2015; Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 8 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Liver; Sites of involvement: Eye / Liver / Peritoneum, NOS.
   Pathology details: Lymph node involved site: Paraaortic; Tumor largest dimension diameter: 7 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 8 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 2192 [Blood test normal range upper: 340].

Other clinical attributes
- Day 0: Weight: 16 kg; Height: 72 cm; BMI: 30.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00164-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Needle Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00164-01C-01-S1-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 50; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-06-00164-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-06-00164-99A: Sample type: Granulocytes; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen; Days to sample procurement: -1 day; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 3; Extranodal involvment other: Intra-peritoneal; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Trucut biopsy; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: para-aortic.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 2192; Immunophenotypic analysis method: Immunohistochemistry.
